Surgical pathology report (de-identified scan), TCGA case TCGA-24-1923, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1923-01A (Primary Tumor).

[page 1 of 4]
TCGA-24-1923

SURGICAL PATHOLOGY REPORT

* Amended *

Patient Name

Address:

Gender:

DOB:

Service:

Location:

MRN:

Hospital #

Accession

Taken:

Received:

Reported:

Physician(s):

Other Related Clinical Data:

DIAGNOSIS:

OVARY, RIGHT, BILATERAL SALPINGO-OOPHORECTOMY

- POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA (SEE SYNOPSIS)
- THE TUMOR INVOLVES THE OVARIAN SURFACE AND AND PARAOVARIAN SOFT TISSUE
- LYMPHATIC-VASCULAR SPACE INVASION ARE IDENTIFIED

OVARY, LEFT, BILATERAL SALPINGO-OOPHORECTOMY

- POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA (SEE SYNOPSIS)
- THE TUMOR INVOLVES THE OVARIAN SURFACE AND AND PARAOVARIAN SOFT TISSUE
- LYMPHATIC-VASCULAR SPACE INVASION ARE IDENTIFIED

FALLOPIAN TUBE, RIGHT, BILATERAL SALPINGO-OOPHORECTOMY

- METASTATIC SEROUS ADENOCARCINOMA

FALLOPIAN TUBE, LEFT, BILATERAL SALPINGO-OOPHORECTOMY

- METASTATIC SEROUS ADENOCARCINOMA

UTERUS WITH CERVIX, TOTAL ABDOMINAL HYSTERECTOMY

- METASTATIC SEROUS ADENOCARCINOMA INVOLVING EXTENSIVELY SEROSA, SUBSEROSAL MYOMETRIUM, ECTOCERVIX AND FOCALLY ENDOCERVIX
- INACTIVE ENDOMETRIUM
- ADENOMYOSIS

BLADDER MUCOSA, BIOPSY

- METASTATIC SEROUS ADENOCARCINOMA

[page 2 of 4]
APPENDIX, APPENDECTOMY

- METASTATIC SEROUS ADENOCARCINOMA

GASTROCOLIC OMENTUM, EXCISION

- METASTATIC SEROUS ADENOCARCINOMA

RECTAL PLAQUE, BIOPSY

- METASTATIC SEROUS ADENOCARCINOMA WITH NECROSIS

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

Intraoperative Consultation:

An intraoperative non-microscopic consultation was obtained and interpreted as: "Called to pick-up 'uterus/cervix/right and left tubes and ovaries' consisting of a 102 gram corpus uteri and cervix with bilateral attached fallopian tubes and ovaries. The ovaries are sectioned and tissue is procured for request. The uterus measures 6.8 cm from fundus to cervix, 3 cm from cornu to cornu, and 4 cm from anterior to posterior. All for permanents,"

Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis.

History:

The patient is a of unstated race, with ovarian cancer. Operative procedure: Evaluation under anesthesia, exploratory laparotomy, transabdominal hysterectomy - bilateral salpingo-oophorectomy, tumor debulking, and appendectomy.

Specimen(s) Received:

- A: HYSTERECTOMY, BSO
- B: BLADDER SEROSA
- C: APPENDIX
- D: GASTRO COLIC OMENTUM, ROUTINE
- E: RECTAL PLAQUE

Gross Description

The specimens are received in five containers of formalin, each labelled with the patient's name. The first container is labelled "uterus/cervix/right and left tubes and ovaries." It consists of a uterus, with dimensions consistent with those in intraoperative consultation, attached cervix, measuring 3 x 3 x 2.5 cm, left and right fallopian tubes, measuring 6.5 cm and 6 cm, respectively, and left and right ovaries measuring 3 x 2.5 x 1 cm each. The specimen has been previously bivalved for fixation. The external surface of cervix and uterus shows irregular adhesions. No recognizable vaginal cuff or parametrial tissue is present. The ectocervix measures 3 x 1 cm anteriorly, and 3.5 x 1.5 cm posteriorly. The reconstituted os is somewhat irregular, measuring 0.5 cm. An area of hemorrhage, otherwise smooth is noted along the posterior ectocervix measuring 1 x 1 cm in extent. The cervical canal measuring 2.5 cm in length shows mucus. A slight irregularity is noted along the anterior endocervical canal with attached mucus, measuring 1 x 1.2 cm. The endometrial

[page 3 of 4]
cavity is triangular and measures 2.5 x 2 cm. The anterior and posterior endomyometrium is diffusely thickened with a smooth, trabeculated appearance. The anterior endomyometrium measures 2.3 cm in thickness and the posterior endomyometrium measures 2.7 cm in the maximally thickened area. The endometrial-myometrial interface is grossly obliterated. The left adnexal structures are congested and edematous in appearance. Adhesions are grossly identified with some firm areas. The fimbriated end of the left fallopian tube is grossly obliterated and shows a soft, grey-white nodule, measuring 0.3 cm in immediate vicinity. The left ovary, although not grossly enlarged, has a nodular, granular outer surface with areas showing exudate. The cut surface is also somewhat nodular and firm. No gross extension of tumor into the meso-ovarian or adjacent, middle-third of fallopian tube is noted. The right fallopian tube is thickened along the middle-third with serosal congestion and exudate on the surface. The fimbriated end is obliterated and somewhat firm. There are areas of congestion and firmness with exudate-like deposits in the left adnexal soft tissue. The right ovary is similar in gross appearance to the left ovary. Labelled A1-A5, anterior cervix with A1 and A2 containing the nodular thickening; A6-A8, posterior cervix; A9 and A10, synchronous sections of anterior endomyometrium; A11 and A12, synchronous sections of posterior endomyometrium; A13, posterior serosal adhesions on uterine corpus; A14, anterior serosal adhesions; A15-A17, left ovary and fallopian tube; A18-A20, right ovary, right adnexa and fallopian tube; A21-A25, the remaining entire cervix; A26 -A33, the remaining entire endometrium. [REDACTED]

The second container is labelled "bladder serosa" and contains an irregular fragment of congested, soft, membranous tissue measuring 3.5 x 2.5 x 0.3 cm. Attached adipose tissue is noted on the smooth surface. The opposite surface is somewhat rough and hemorrhagic. Serially sectioned. Labelled B1 and B2. [REDACTED]

The third container is labelled "appendix" and contains an appendix with attached fat, measuring 6 cm in length. The tip is swollen and congested and shows grey-white exudate on the surface. It measures 1.2 cm in greatest dimension. The cut surface in the swollen area shows an obliterated lumen with no gross evidence of tumor involvement. Serial sectioning through the remaining appendix shows a thin, 0.3 cm appendix with obliterated lumen. The adjacent adipose tissue is grossly unremarkable. Labelled C1 and C2, entire firm area around putative tip; C3, random appendix. [REDACTED]

The fourth container is labelled "gastro-colic omentum." It consists of a stretch of omentum, measuring 40 x 18 x 3.5 cm in maximum dimensions. There are geographic areas of thickening and omental caking, involving the edges of the omentum. Cut sections of these areas show grey-white, firm cut surface with areas of necrosis. Random representative sections labelled D1-D4. [REDACTED]

The fifth container is labelled "rectal plaque" and contains multiple plaque-like, hemorrhagic fragments measuring 1.5 cc in aggregate. Labelled E1. Jar 0.

Synopsis

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

1. A neoplasm is PRESENT
2. The HISTOLOGIC DIAGNOSIS is:
Serous adenocarcinoma
3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are:
Right and left ovary (synchronous primary tumors)
4. The FIGO GRADE of the tumor is:
III (Tumor composed of >50% solid cellular nests)
5. The NUCLEAR (BRODERS') GRADE of the tumor is:

[page 4 of 4]
- G3 (Poorly-differentiated)
6. Tumor IS identified on the ovarian surface(s).
7. Tumor DOES invade the mesovarium.
8. Tumor DOES invade the adjacent fallopian tube.
9. Tumor DOES invade the pelvic soft tissue.
10. Tumor involvement of the pelvic peritoneum is PRESENT.
11. Metastatic involvement of the EXTRAPELVIC PERITONEUM is PRESENT.
12. Metastatic involvement of the omentum is PRESENT.
13. The maximum dimension of tumor implants outside the true pelvis is >2 cm.
15. Metastatic involvement of the endometrium is ABSENT.
16. Regional lymph node metastases CANNOT BE EVALUATED.
17. The total number of regional lymph nodes examined is 0.
18. The total number of metastatically-involved regional lymph nodes cannot be evaluated.
19. DETAILED STAGING INFORMATION:

Based on the above information, the PRIMARY TUMOR is
classified as:

TNM Scheme	FIGO Scheme	Definition	
T3c		IIIC	Macroscopic peritoneal
metastasis beyond true pelvis measuring > 2 cm in greatest dimension,			

THE REGIONAL LYMPH NODES are classified as:

NX (Nodal status cannot be assessed)

THE STATUS OF DISTANT TUMOR SITES is classified as:

MX (Status cannot be assessed)

20. The FINAL AJCC/UICC/FIGO STAGE IS:

AJCC/UICC/FIGO

X

Insufficient data to assign stage

Amendments

Reason: This case is being amended to correct the Microscopic description field.

Source: NCI Genomic Data Commons file f1d92458-8537-4946-bbc4-bedb6901dcd0 (TCGA-24-1923.6AE8158A-E236-4CC0-88D2-50756216F0E7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).